Somatic mutation profile of tumor specimen TCGA-US-A779-01A (aliquot TCGA-US-A779-01A-11D-A32N-08) from TCGA case TCGA-US-A779, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 54.9 years (20,051 days).
Specimen TCGA-US-A779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dffd7015-436c-4127-846e-0dd30fe07162.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-US-A779-11A (Solid Tissue Normal), aliquot TCGA-US-A779-11A-11D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4eb5a790-7392-479d-b717-a924bd1c4b67

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Splice Site 1, Nonsense Mutation 1, Translation Start Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/106 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADRA2B | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787924; called by muse, mutect2, varscan2
- BEND2 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 241/1049 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs868376547, COSV66221592; called by muse, mutect2, varscan2
- BMP1 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 133/619 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as rs150161793, COSV100115525; called by muse, mutect2, varscan2
- BRSK1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1308344035, COSV100474770; called by muse, mutect2, varscan2
- CSMD3 | c.2273G>A p.R758Q (on ENST00000297405 / NM_001363185.1; = p.R654Q on NM_052900.3) | Missense Mutation (SNP) | VAF 82/451 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1286397306, COSV52093344; called by muse, mutect2, varscan2
- FAT3 | c.11729G>A p.R3910H | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.116); catalogued as rs376837097, COSV53076599; called by muse, mutect2, varscan2
- HACD3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV56012113; called by muse, mutect2, varscan2
- HIF3A | c.1162A>G p.I388V (on ENST00000377670 / NM_152795.4; = p.I319V on NM_022462.4) | Missense Mutation (SNP) | VAF 242/883 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99356144; called by muse, mutect2, varscan2
- IL22RA1 | c.1669A>G p.T557A | Missense Mutation (SNP) | VAF 102/437 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54629525; called by muse, mutect2, varscan2
- KDM6A | c.2471dup p.T825Nfs*10 | Frame Shift Ins (INS) | VAF 24/170 reads (14%) | catalogued as COSV65046537; called by mutect2, pindel, varscan2
- LRRC10 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 103/430 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64060549; called by muse, mutect2, varscan2
- LTBP2 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs765072306, COSV100001196; called by muse, mutect2
- NYNRIN | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 147/524 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV101230733; called by muse, mutect2, varscan2
- PLXNB2 | c.5087C>G p.P1696R | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834374, COSV63782819; called by muse, mutect2, varscan2
- RAD21 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.558); catalogued as COSV52061494; called by muse, mutect2, varscan2
- RBMS1 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100817141; called by muse, mutect2, varscan2
- RGS12 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 105/410 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60907806; called by muse, mutect2, varscan2
- RYBP | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 66/230 reads (29%) | catalogued as COSV72180817; called by muse, mutect2, varscan2
- TP53 | c.557del p.D186Vfs*61 | Frame Shift Del (DEL) | VAF 95/239 reads (40%) | catalogued as COSV52678040, COSV53587542; called by mutect2, pindel, varscan2
- TRIP11 | c.3520G>C p.D1174H | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104389145, COSV99971312; called by muse, mutect2
- VWC2 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs866218265, COSV100514969; called by muse, mutect2
- ZNF148 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 62/371 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs376674595; called by muse, mutect2, varscan2
- ZNF184 | c.578T>A p.L193H | Missense Mutation (SNP) | VAF 78/692 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99280197; called by muse, mutect2, varscan2
- SLC5A6 | c.849_875+10del p.X283_splice | Splice Site (DEL) | VAF 33/273 reads (12%) | called by mutect2, pindel
- CFH | c.3321A>C p.G1107= | Silent (SNP) | VAF 137/589 reads (23%) | catalogued as COSV100810371; called by muse, mutect2, varscan2
- FAM3C | c.522T>A p.T174= | Silent (SNP) | VAF 54/254 reads (21%) | catalogued as COSV100739939; called by muse, mutect2, varscan2
- MMRN1 | c.3165G>A p.T1055= | Silent (SNP) | VAF 98/285 reads (34%) | catalogued as rs778903851, COSV53339284, COSV99307924; called by muse, mutect2, varscan2
- MRPL34 | c.210G>T p.L70= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV99395569; called by muse, mutect2, varscan2
- ZC3H7B | c.1506C>T p.F502= | Silent (SNP) | VAF 36/1217 reads (3%) | catalogued as COSV100687923; called by muse, mutect2
